Gene-level copy-number profile of tumor specimen TCGA-DE-A4MB-01A from TCGA case TCGA-DE-A4MB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 79.4 years (29,011 days).
Specimen TCGA-DE-A4MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THCA.752320c9-6941-426d-b913-75123055b9c7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DE-A4MB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 401 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cccd19b3-ca0b-4299-bd11-b74221f02357

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,506; copy number 1: 591; copy number 2: 52,708; copy number 3: 1,990; copy number 4: 747; copy number 5: 1,029; copy number 6: 1,600; copy number 7: 32; copy number 13: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DE-A4MB-01A-11D-A256-01): tumor purity 0.67, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 985 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:45,480,030–45,480,136, 1 gene: RNU6-931P.
- chr5:12,553,890–12,804,363, 4 genes: AC106771.1, LINC01194, AC106794.2, AC106794.1.
- chr5:178,825,382–178,842,235, 3 genes: AC126915.2, AC126915.1, AC126915.3.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:94,555,054–138,203,325, 972 genes (within-gene range 0–1) (broad region; genes not listed).
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,680 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–166,580,705, 925 genes, copy number 5 (broad region; genes not listed).
- chr1:166,975,582–248,919,946, 1,661 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:88,765,807–88,806,612, 1 gene, copy number 6: ANKRD36BP2.
- chr3:75,384,059–75,785,583, 24 genes, copy number 6: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273.
- chr4:49,203,171–49,589,529, 19 genes, copy number 13: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:46,028,804–46,028,892, 1 gene, copy number 6: AC118650.1.
- chr14:105,419,820–105,499,575, 6 genes, copy number 5 (within-gene range 2–5): MTA1, AL928654.2, CRIP2, CRIP1, AL928654.3, TEDC1.
- chr15:25,170,723–25,223,327, 29 genes, copy number 7: SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29.
- chr16:11,555–57,669, 8 genes, copy number 6: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25.
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 2–5): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 5: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 591. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
